Somatic mutation profile of tumor specimen 0DQZ3P from CCDI case PBBYCC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma in adenomatous polyposis coli; Tissue or organ of origin: Sigmoid colon; Age at diagnosis: 14.9 years (5,453 days).
Specimen 0DQZ3P: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f66df5b9-60a5-4565-8f4c-e2e735f9a616.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQZ3C (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0bfef68e-4458-441a-a143-17d4e13db81f

The open-access MAF lists 80 somatic variants for this specimen: 50 protein-altering or splice-affecting, 12 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Intron 14, Silent 12, Splice Region 2, Splice Site 2, 3'UTR 2, 5'UTR 2, Nonsense Mutation 1, Translation Start Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.329G>T p.R110L | Missense Mutation (SNP) | VAF 311/562 reads (55%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.343); catalogued as rs11540654, CM115383, CM134053, CM984590, COSV52662399, COSV52668419, COSV52680444, COSV53132492; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS9 | c.4324G>A p.D1442N | Missense Mutation (SNP) | VAF 97/1342 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as rs373632346; called by muse, mutect2
- ANKRD2 | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 260/662 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1436065232, COSV53969796; called by muse, mutect2, varscan2
- CFAP300 | c.431G>A p.R144Q | Missense Mutation (SNP) | VAF 235/626 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as rs751349174, COSV71570599; called by muse, mutect2, varscan2
- CPAMD8 | c.3716G>A p.R1239H (on ENST00000651564; = p.R1192H on NM_015692.5) | Missense Mutation (SNP) | VAF 184/472 reads (39%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as rs371395530, COSV71596271; called by muse, mutect2, varscan2
- DOCK11 | c.4366G>A p.V1456I | Missense Mutation (SNP) | VAF 49/700 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.2); catalogued as rs767222703; called by muse, mutect2
- ENOX1 | c.440G>T p.G147V | Missense Mutation (SNP) | VAF 254/936 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99817036; called by muse, mutect2, varscan2
- EVA1A | c.301C>T p.R101C | Missense Mutation (SNP) | VAF 423/941 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV52060059; called by muse, mutect2, varscan2
- LRRC56 | c.334G>A p.G112S | Missense Mutation (SNP) | VAF 182/428 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs540874265; called by muse, mutect2, varscan2
- MCF2L | c.445G>A p.V149I (on ENST00000375608; = p.V117I on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 83/312 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.014); catalogued as rs751605602, COSV100982876; called by muse, mutect2, varscan2
- MUC5AC | c.14878G>A p.V4960M | Missense Mutation (SNP) | VAF 51/401 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761229771, COSV64370619; called by muse, mutect2, varscan2
- NBEA | c.6227G>A p.R2076H | Missense Mutation (SNP) | VAF 84/1247 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1172372804, COSV100077859; called by muse, mutect2
- OLFM1 | c.1099G>A p.V367M (on ENST00000371793 / NM_001282611.2; = p.V349M on NM_014279.5) | Missense Mutation (SNP) | VAF 139/312 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs950757823, COSV99423363; called by muse, mutect2, varscan2
- PLEKHG4B | c.223C>T p.R75W (on ENST00000283426; = p.R431W on NM_052909.5) | Missense Mutation (SNP) | VAF 22/304 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as rs369792305; called by muse, mutect2
- REPIN1 | c.538G>A p.G180S | Missense Mutation (SNP) | VAF 36/562 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.302); catalogued as rs1472966438, COSV101262730; called by muse, mutect2
- SACS | c.11354G>T p.R3785M | Missense Mutation (SNP) | VAF 306/1096 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.169); catalogued as COSV66534141; called by mutect2, varscan2
- ST14 | c.1873G>A p.E625K | Missense Mutation (SNP) | VAF 251/772 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1333246624, COSV53831383; called by muse, mutect2, varscan2
- TCEAL6 | c.353C>T p.T118M | Missense Mutation (SNP) | VAF 416/617 reads (67%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.998); catalogued as rs782217171, COSV65653883; called by muse, mutect2, varscan2
- ADGB | c.1199T>C p.V400A | Missense Mutation (SNP) | VAF 48/838 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.027); called by muse, mutect2
- ANXA3 | c.715T>A p.L239I | Missense Mutation (SNP) | VAF 107/853 reads (13%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- CALN1 | c.266A>T p.D89V (on ENST00000329008 / NM_001017440.3; = p.D131V on NM_031468.4) | Missense Mutation (SNP) | VAF 252/903 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CHORDC1 | c.564-1G>C p.X188_splice | Splice Site (SNP) | VAF 22/711 reads (3%) | called by muse, mutect2
- CNTN3 | c.95C>A p.P32H | Missense Mutation (SNP) | VAF 301/790 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL20A1 | c.3530G>C p.G1177A | Missense Mutation (SNP) | VAF 40/1324 reads (3%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2
- CROCC2 | c.4040G>A p.R1347Q | Missense Mutation (SNP) | VAF 220/916 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- CYP7B1 | c.12A>C p.E4D | Missense Mutation (SNP) | VAF 58/165 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- DIP2B | c.2686C>G p.L896V | Missense Mutation (SNP) | VAF 133/989 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DPYSL4 | c.76A>G p.N26D | Missense Mutation (SNP) | VAF 159/631 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EPB41L4B | c.118G>C p.G40R | Missense Mutation (SNP) | VAF 34/238 reads (14%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- FRYL | c.6712T>C p.Y2238H | Missense Mutation (SNP) | VAF 50/340 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- GOLGA4 | c.3395T>C p.L1132P | Missense Mutation (SNP) | VAF 82/1358 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- HELQ | c.493C>A p.L165I | Missense Mutation (SNP) | VAF 171/1071 reads (16%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- IGSF9 | c.641G>T p.S214I | Missense Mutation (SNP) | VAF 52/926 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2
- KIAA1671 | c.1559C>T p.S520F | Missense Mutation (SNP) | VAF 417/1080 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- LRP1B | c.7642G>T p.E2548* | Nonsense Mutation (SNP) | VAF 71/1068 reads (7%) | called by muse, mutect2
- MSH4 | c.1233C>T p.V411= | Splice Region (SNP) | VAF 90/393 reads (23%) | called by muse, mutect2, varscan2
- NETO1 | c.1033G>C p.V345L | Missense Mutation (SNP) | VAF 422/865 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- NOL4L | c.451G>A p.A151T | Missense Mutation (SNP) | VAF 126/2407 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PCDHA13 | c.1219T>A p.L407I | Missense Mutation (SNP) | VAF 64/736 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.908); called by muse, mutect2
- PDE6B | c.1308C>A p.D436E | Missense Mutation (SNP) | VAF 160/569 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- QPRT | c.860C>G p.A287G | Missense Mutation (SNP) | VAF 384/1173 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- RASGRP3 | c.1164G>A p.Q388= (on ENST00000402538 / NM_001349975.2; = p.X388_splice on NM_015376.2 and 4 other RefSeq transcripts) | Splice Region (SNP) | VAF 99/761 reads (13%) | called by muse, mutect2, varscan2
- RELN | c.6952T>G p.S2318A | Missense Mutation (SNP) | VAF 48/841 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.7); called by muse, mutect2
- SAGE1 | c.2462dup p.K822Efs*3 | Frame Shift Ins (INS) | VAF 84/465 reads (18%) | called by mutect2, pindel, varscan2
- SCGB2A2 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 224/669 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SF3B4 | c.209C>A p.A70D | Missense Mutation (SNP) | VAF 54/1280 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SIRT3 | c.317T>A p.V106E | Missense Mutation (SNP) | VAF 133/1587 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.143); called by muse, mutect2
- TXNDC5 | c.414-1G>T p.X138_splice | Splice Site (SNP) | VAF 62/1018 reads (6%) | called by muse, mutect2
- ZNF263 | c.841G>C p.V281L | Missense Mutation (SNP) | VAF 150/516 reads (29%) | SIFT tolerated (0.76); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZSCAN5B | c.1357A>G p.N453D | Missense Mutation (SNP) | VAF 38/568 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.12); called by muse, mutect2
- ANO10 | c.561C>T p.Y187= | Silent (SNP) | VAF 62/1040 reads (6%) | catalogued as rs762719135; called by muse, mutect2
- DGCR8 | c.1029C>T p.H343= | Silent (SNP) | VAF 245/502 reads (49%) | catalogued as rs779520821; ClinVar: likely benign; called by muse, mutect2, varscan2
- DGKD | c.2007C>T p.F669= (on ENST00000264057 / NM_152879.3; = p.F625= on NM_003648.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 50/809 reads (6%) | catalogued as rs754569132; called by muse, mutect2
- HMCN2 | c.8472C>A p.A2824= | Silent (SNP) | VAF 178/823 reads (22%) | called by muse, mutect2, varscan2
- IRAG1 | c.2142C>A p.P714= | Silent (SNP) | VAF 106/1150 reads (9%) | called by muse, mutect2
- MAMDC4 | c.2511G>A p.S837= (on ENST00000445819; = p.S758= on NM_206920.3) | Silent (SNP) | VAF 56/686 reads (8%) | catalogued as rs1486634243; called by muse, mutect2
- MYO15B | c.2478C>T p.I826= | Silent (SNP) | VAF 311/1066 reads (29%) | catalogued as rs1346855091; called by muse, mutect2, varscan2
- NPAP1 | c.2046G>T p.V682= | Silent (SNP) | VAF 289/808 reads (36%) | catalogued as COSV61507344; called by muse, mutect2, varscan2
- SLC19A3 | c.567C>T p.F189= | Silent (SNP) | VAF 382/1602 reads (24%) | catalogued as rs373262430; called by muse, mutect2, varscan2
- SNX32 | c.1062C>T p.S354= | Silent (SNP) | VAF 47/826 reads (6%) | catalogued as rs768920081; called by muse, mutect2
- WDR62 | c.786G>T p.R262= | Silent (SNP) | VAF 343/819 reads (42%) | called by muse, mutect2, varscan2
- WDR90 | c.4842G>A p.E1614= | Silent (SNP) | VAF 219/669 reads (33%) | catalogued as rs1271079728; called by muse, mutect2, varscan2
- AFMID | c.468-19C>T | Intron (SNP) | VAF 74/246 reads (30%) | catalogued as rs1156851172; called by muse, mutect2, varscan2
- CLPP | c.*56C>A | 3'UTR (SNP) | VAF 16/160 reads (10%) | called by muse, mutect2, varscan2
- CYFIP2 | c.795+14G>A | Intron (SNP) | VAF 102/799 reads (13%) | called by muse, mutect2, varscan2
- FAM214A | c.2808+27T>G | Intron (SNP) | VAF 112/543 reads (21%) | called by muse, mutect2, varscan2
- GSTA4 | c.88-68A>T | Intron (SNP) | VAF 66/162 reads (41%) | called by muse, mutect2, varscan2
- IP6K2 | c.202+650A>G | Intron (SNP) | VAF 152/515 reads (30%) | called by muse, mutect2, varscan2
- KRAS | c.*173G>T | 3'UTR (SNP) | VAF 42/141 reads (30%) | called by muse, mutect2, varscan2
- LIME1 | c.269-61C>G | Intron (SNP) | VAF 24/484 reads (5%) | called by muse, mutect2
- PIP4K2C | c.-23C>T | 5'UTR (SNP) | VAF 36/308 reads (12%) | catalogued as rs559567144; called by muse, mutect2, varscan2
- POLR3E | c.165+40G>C | Intron (SNP) | VAF 244/650 reads (38%) | called by muse, mutect2, varscan2
- R3HDM1 | c.1475-9del | Intron (DEL) | VAF 232/671 reads (35%) | called by mutect2, pindel, varscan2
- SCARB1 | c.-75C>T | 5'UTR (SNP) | VAF 16/45 reads (36%) | called by muse, mutect2, varscan2
- SCARB2 | c.705-82A>G | Intron (SNP) | VAF 26/114 reads (23%) | called by muse, mutect2, varscan2
- SMARCD1 | c.1393-84A>C | Intron (SNP) | VAF 91/245 reads (37%) | called by muse, mutect2, varscan2
- TMEM132A | c.1357-27G>A | Intron (SNP) | VAF 192/638 reads (30%) | catalogued as rs543356280; called by muse, mutect2
- UBQLN1 | c.1333-42A>T | Intron (SNP) | VAF 80/190 reads (42%) | called by muse, mutect2, varscan2
- XPNPEP1 | c.1392-50G>T | Intron (SNP) | VAF 48/806 reads (6%) | called by muse, mutect2
- YBX3 | c.360+77T>C | Intron (SNP) | VAF 66/258 reads (26%) | called by muse, mutect2, varscan2
